Surgical pathology report (de-identified scan), TCGA case TCGA-CS-6186, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Thomas Jefferson University, specimen TCGA-CS-6186-01A (Primary Tumor).

[page 1 of 5]
[REDACTED]

[REDACTED]

SURGICAL PATHOLOGY REPORT

FINAL DIAGNOSIS:

1. Right post central tumor consistent with glioma: OLIGOASTROCYTOMA WITH FOCAL ANAPLASTIC CHANGES. SEE MICROSCOPIC DESCRIPTION. SEE COMMENT.
2. SPECIMEN NOT RECEIVED: SPECIMEN DESIGNATED #2 NOT RECEIVED IN SURGICAL PATHOLOGY
3. Right post central tumor consistent with glioma: OLIGOASTROCYTOMA WITH FOCAL ANAPLASTIC CHANGES. SEE MICROSCOPIC DESCRIPTION. SEE COMMENT.

Comment:

This oligoastrocytoma has small areas of increased cellularity, increase pleomorphism and increased mitotic rate. The Ki67 proliferation index in these small areas of both specimen #1 and #3 approach 15%. Additionally, a small focus of endothelial proliferation is identified on the actual frozen tissue section slides of specimen #1 but this endothelial proliferation area is not present on the permanent sections. While the major portions of both specimens #1 and #3 display WHO grade II features, the identification of the small foci of anaplasia and elevated Ki67 proliferation indices suggest that this oligoastrocytoma will behave as an anaplastic oligoastrocytoma, WHO grade III. Clinical correlation recommended.

[REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

Specimen #1 is composed primarily of neoplastic fibrillary astrocytes. A small focus of endothelial proliferation is identified on the actual frozen section slides. The Ki67 proliferation index and mitotic rate is low in the major portion of specimen #1. A very small focus of increase cellularity is however present on the permanent sections of specimen #1. In this small focus of increase cellularity of specimen #1, the Ki67 proliferation index approaches 15%. Specimen #3 shows

[page 2 of 5]
areas of oligodendroglial differentiation. Microcalcifications are identified in areas of tumor is specimen #3. Small foci of increased cellularity, increased cellular pleomorphism and increased mitotic activity are identified in specimen #3. The Ki67 proliferation index in these areas of increased cellularity and pleomorphism in specimen #3 approaches 15%.

This tumor is an oligoastrocytoma. While the major portions of both specimens #1 and #3 display WHO grade II features, the identification of the small foci of anaplasia and elevated Ki67 proliferation indices in both specimens suggest that this oligoastrocytoma will behave as an anaplastic oligoastrocytoma, WHO grade III. Clinical correlation recommended.

A separate report with the results of FISH analysis of 1p19q status of the tumor will be issued.

Frozen Section Diagnosis:

1. Right post central tumor consistent with glioma: Astrocytic neoplasm with high grade features. Frozen section diagnosis by [REDACTED]

Clinical History and Diagnosis:

Right brain mass

Source of Specimen:

- 1: Right post central tumor consistent with glioma
- 2: SPECIMEN NOT RECEIVED
- 3: Right post central tumor consistent with glioma

Gross Description:

1. Right post central tumor consistent with glioma: Received fresh for frozen section in a specimen container labeled with the patient's name and "right post central tumor consistent with glioma" is a 1 x 0.8 x 0.3 cm aggregate of tan-pink soft tissue. Approximately 80% of the specimen is frozen for intraoperative consultation and the entire specimen is submitted in 2 cassettes the permanent sections. Touch preps are prepared.

Designations

[page 3 of 5]
[REDACTED]

A. FSC

B. Remainder of specimen

3. Right post central tumor consistent with glioma: Received in formalin in a specimen container labeled with the patient's name and "right post central tumor consistent with glioma" are 3 fragments of tan-pink soft tissue that measure 1.5 x 0.8 x 0.5 cm in aggregate. The entire specimen is submitted in one cassette.

Histology Laboratory

[REDACTED]

Part 3: Right post central tumor consistent with glioma

[REDACTED]

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of [REDACTED] Applied Immunohistochemistry, [REDACTED]

2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

[REDACTED]

[REDACTED]

EGFR pharmDx [REDACTED] Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]

[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the Clinical Laboratory of [REDACTED]

[REDACTED]

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[page 4 of 5]
[REDACTED]
[REDACTED]

MEDICAL GENETICS REPORT

EVALUATION:

ASSAY PERFORMED: del(1p)del(19q) BY FLUORESCENT IN-SITU HYBRIDIZATION (FISH)

RESULT: Negative for the deletion of 1p
Negative for the deletion of 19q

[REDACTED]

1p36/1q24

Number of Nuclei scored: 300

Ratio of 1p/1q: 0.93

% cells with del 1p: 27%

19q13/19p13

Number of Nuclei scored: 200

Ratio of 19q/19p: 0.98

% cells with del 19q: 5.5%

INTERPRETATION: The results are within the normal range and suggest absence of deletions of 1p and 19q in this glioma ([REDACTED]). del (1p) and del(19q) has been observed in glioma specimens, especially oligodendrogliomas. Clinical and pathologic correlation is recommended.

[REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Data Analysis:

DESCRIPTION OF THE ASSAY: 1p and 19q FISH studies were performed on paraffin embedded tumor sections. Two hybridizations were performed: one with a 1p/1q probe/control pair and one with a 19q/19p probe/control pair. The 19q and 1p probes map to regions that are commonly deleted in gliomas. The nuclei are counterstained with DAPI and the cells examined by epi-fluorescence microscopy. The total

[page 5 of 5]
[REDACTED]
number of counts for each probe is determined in 200 cells and the ratios of 1p/1q and 19q/19p are calculated.

Normal range: The normal ratio is approximately 1. Any ratio > 0.80 is considered normal.

LIMITATIONS: Low levels of malignant cells in the specimen can result in a false negative result. As with all laboratory tests, sampling error and other factors may affect the outcome of the assay. Correlation of results with other clinical and laboratory data should be obtained.

COMMENT: This test was developed and its performance characteristics determined by the Molecular Pathology Laboratory at [REDACTED]. It has not been cleared or approved by the U.S. Food and Drug Administration.

This test is not to be used as a diagnostic procedure without confirmation of the diagnosis by another medically established product or procedure.

Clinical History and Diagnosis:

Right post central tumor consistent with Glioma: Oligoastrocytoma with Focal anaplastic changes.

Source of Specimen:

1: FISH-BRAIN

Gross Description:

[REDACTED]
Formalin-fixed paraffin-embedded tissue

Histology Laboratory

[REDACTED]

Source: NCI Genomic Data Commons file 5dc40470-930d-46a5-b358-fad6e65d739f (TCGA-CS-6186.AE1D6C04-B80B-4DA5-9C19-0A0FFAF9A332.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).